Somatic mutation profile of tumor specimen CDDP-ACRT-TTP1-A (aliquot CDDP-ACRT-TTP1-A-1-0-D-A572-36) from CDDP_EAGLE case CDDP-ACRT, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 56 years.
Specimen CDDP-ACRT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f630784-5b1e-4dba-a357-c515aba2c78a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ACRT-NB1-A (Blood Derived Normal), aliquot CDDP-ACRT-NB1-A-1-0-D-A572-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3cb5654d-23d9-4d1c-b925-3f53e45241ae

The open-access MAF lists 52 somatic variants for this specimen: 32 protein-altering or splice-affecting, 11 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 11, Intron 4, In Frame Del 3, 3'UTR 2, Nonsense Mutation 2, 5'UTR 2, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 25/190 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 25/203 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1057519947, COSV59042211, COSV59042295; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACVR2B | c.1227G>C p.E409D | Missense Mutation (SNP) | VAF 40/277 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.088); catalogued as COSV61702130; called by muse, mutect2, varscan2
- B4GALT1 | c.210C>G p.I70M | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as rs769929115; called by muse, mutect2, varscan2
- CACNA1H | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 112/860 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs372851683; called by muse, mutect2, varscan2
- FAT4 | c.8443G>T p.D2815Y | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58681907; called by mutect2, varscan2
- H3C3 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as rs1376372933, COSV63550920; called by muse, mutect2, varscan2
- LAX1 | c.242C>T p.T81I | Missense Mutation (SNP) | VAF 92/347 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1180526639, COSV65849243; called by muse, mutect2, varscan2
- LGALS3BP | c.1639G>T p.A547S | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.132); catalogued as COSV53164821; called by muse, mutect2, varscan2
- MGAT4C | c.141T>A p.Y47* | Nonsense Mutation (SNP) | VAF 7/65 reads (11%) | catalogued as COSV100153524; called by muse, varscan2
- NDUFB9 | c.133A>G p.R45G | Missense Mutation (SNP) | VAF 71/981 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV52674853; called by muse, mutect2
- OVCH2 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 29/248 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as COSV71952792; called by muse, mutect2, varscan2
- PTAFR | c.274G>A p.V92M | Missense Mutation (SNP) | VAF 59/415 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.598); catalogued as rs760341493, COSV59536659; called by muse, mutect2, varscan2
- SLC8A2 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 40/229 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1470448704, COSV52639393, COSV99369865, COSV99370429; called by muse, mutect2, varscan2
- SUN1 | c.638C>T p.S213F (on ENST00000405266 / NM_001367651.1; = p.S163F on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 148/813 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV61778095, COSV61778128; called by muse, mutect2, varscan2
- UBR5 | c.3628G>A p.E1210K | Missense Mutation (SNP) | VAF 73/538 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55285282; called by muse, mutect2, varscan2
- UBR5 | c.1948C>T p.Q650* | Nonsense Mutation (SNP) | VAF 100/682 reads (15%) | catalogued as COSV55285297; called by muse, varscan2
- WDR43 | c.1533G>C p.K511N | Missense Mutation (SNP) | VAF 18/359 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.515); catalogued as COSV68019377; called by muse, mutect2
- CEBPA | c.152_154del p.P51del | In Frame Del (DEL) | VAF 26/226 reads (12%) | called by mutect2, pindel
- CPS1 | c.3190C>A p.L1064M | Missense Mutation (SNP) | VAF 16/435 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2
- DENND3 | c.3198G>C p.K1066N | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2
- FOXK1 | c.2087C>T p.S696F | Missense Mutation (SNP) | VAF 42/544 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.365); called by muse, mutect2
- FYCO1 | c.2264G>A p.G755E | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KNDC1 | c.4157_4162del p.N1386_P1387del | In Frame Del (DEL) | VAF 21/142 reads (15%) | called by mutect2, pindel, varscan2
- MGAM | c.4485-1G>C p.X1495_splice | Splice Site (SNP) | VAF 12/185 reads (6%) | called by muse, mutect2
- MYOM3 | c.3020A>C p.K1007T | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.258); called by muse, mutect2
- PCDHGB4 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 19/204 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.216); called by muse, mutect2
- PROS1 | c.248C>G p.P83R | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF157 | c.1683_1697del p.S562_E566del | In Frame Del (DEL) | VAF 10/64 reads (16%) | called by mutect2, pindel
- SPAG1 | c.218G>A p.R73K | Missense Mutation (SNP) | VAF 62/1298 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.311); called by muse, mutect2
- ZNF676 | c.1574C>T p.T525I (on ENST00000650058; = p.T493I on NM_001001411.3) | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZYG11B | c.1661A>T p.E554V | Missense Mutation (SNP) | VAF 37/308 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- AP3S2 | c.573G>A p.Q191= | Silent (SNP) | VAF 23/163 reads (14%) | catalogued as COSV60518167; called by muse, mutect2, varscan2
- DPEP3 | c.738A>C p.G246= | Silent (SNP) | VAF 65/283 reads (23%) | called by muse, mutect2, varscan2
- FAT3 | c.11964G>A p.S3988= | Silent (SNP) | VAF 35/296 reads (12%) | catalogued as rs749612005, COSV53103455; called by muse, mutect2, varscan2
- FOXK1 | c.2088C>T p.S696= | Silent (SNP) | VAF 44/547 reads (8%) | called by muse, mutect2
- GABARAP | c.315C>G p.L105= | Silent (SNP) | VAF 38/194 reads (20%) | catalogued as COSV56641852; called by muse, mutect2, varscan2
- MAP1A | c.828C>A p.I276= | Silent (SNP) | VAF 14/262 reads (5%) | catalogued as COSV55807506; called by muse, mutect2
- PARP1 | c.2442C>T p.I814= | Silent (SNP) | VAF 76/606 reads (13%) | catalogued as COSV64690149; called by muse, mutect2, varscan2
- RNF11 | c.369G>A p.L123= | Silent (SNP) | VAF 35/315 reads (11%) | catalogued as COSV54376331; called by muse, mutect2, varscan2
- SHANK2 | c.2814C>T p.S938= | Silent (SNP) | VAF 85/495 reads (17%) | catalogued as rs1406552881, COSV53587260; called by muse, mutect2, varscan2
- TRIM35 | c.264G>A p.E88= | Silent (SNP) | VAF 56/414 reads (14%) | catalogued as rs1325631983, COSV57754973; called by muse, mutect2, varscan2
- TTI2 | c.45T>A p.S15= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as rs776148816, COSV62452467; called by muse, mutect2, varscan2
- ANKRD42 | c.502+1568C>G | Intron (SNP) | VAF 19/109 reads (17%) | catalogued as COSV52615094; called by muse, mutect2, varscan2
- BRD7 | c.49+21C>G | Intron (SNP) | VAF 23/362 reads (6%) | called by muse, mutect2
- EBF1 | c.*27_*28del | 3'UTR (DEL) | VAF 25/159 reads (16%) | called by mutect2, pindel, varscan2
- EIF2B1 | c.-51A>G | 5'UTR (SNP) | VAF 37/216 reads (17%) | called by muse, mutect2, varscan2
- FOXI2 | chr10:127736307 C>T | 5'Flank (SNP) | VAF 14/104 reads (13%) | called by muse, mutect2
- HOXA11 | c.*33C>T | 3'UTR (SNP) | VAF 70/481 reads (15%) | catalogued as rs1331343541; called by muse, mutect2, varscan2
- PAPSS2 | c.-40C>G | 5'UTR (SNP) | VAF 65/391 reads (17%) | catalogued as rs113301789; called by muse, mutect2, varscan2
- RIMS2 | c.2084-942G>C | Intron (SNP) | VAF 46/732 reads (6%) | catalogued as rs910081914; called by muse, mutect2
- ZNF17 | c.15+2191G>A | Intron (SNP) | VAF 29/213 reads (14%) | called by muse, mutect2, varscan2
